CCDI case PBCHXM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d32d1d78-8309-4c4f-a63b-4cc8fc504a37

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,371 days).

Biospecimens (3 samples)
- Sample 0DSA01: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSA09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSA1H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
